Somatic mutation profile of tumor specimen 0DPAOK from CCDI case PBCDES, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,480 days).
Specimen 0DPAOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d134d16-2816-4600-a996-ff4ab6f4163e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAOA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca85f09d-fa20-4341-8542-929f21850d2b

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 4, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.4480C>T p.R1494* | Nonsense Mutation (SNP) | VAF 235/584 reads (40%) | catalogued as rs587783442, CM066002; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 422/945 reads (45%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 158/370 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 192/470 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV67134703; called by muse, mutect2, varscan2
- ADORA2A | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 233/483 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.823); catalogued as rs199725333, COSV58379426; called by muse, mutect2, varscan2
- ANK3 | c.12037C>T p.R4013C | Missense Mutation (SNP) | VAF 492/1050 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs755321457, COSV55068312; called by muse, mutect2, varscan2
- CACNA1C | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 236/491 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1429990170, COSV59701122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC171 | c.2968C>T p.R990C | Missense Mutation (SNP) | VAF 195/457 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs753856863, COSV52641994; called by muse, mutect2, varscan2
- CD300LG | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 218/449 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs904244227, COSV53224267; called by muse, mutect2, varscan2
- COL10A1 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 198/418 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as rs143769451, COSV54574590; called by muse, mutect2, varscan2
- DNAH3 | c.4202G>A p.R1401Q | Missense Mutation (SNP) | VAF 265/616 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879199308, COSV99766366; called by muse, mutect2, varscan2
- NIM1K | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 204/420 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770268418, COSV58139511; called by muse, mutect2, varscan2
- PARP8 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 182/390 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1477888806; called by muse, mutect2, varscan2
- TJP3 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs367879011; called by muse, mutect2, varscan2
- TRPM4 | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 298/689 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372848098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZEB2 | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 20/600 reads (3%) | catalogued as COSV57951368; called by muse, mutect2
- DNAH6 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 125/279 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- IRF2BP1 | c.775T>G p.F259V | Missense Mutation (SNP) | VAF 255/542 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAP3K14 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 333/742 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MUC16 | c.36884C>A p.A12295D | Missense Mutation (SNP) | VAF 216/470 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TDRD6 | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 66/641 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, varscan2
- VGLL4 | c.255del p.N86Tfs*28 | Frame Shift Del (DEL) | VAF 172/475 reads (36%) | called by mutect2, pindel, varscan2
- AP3M2 | c.375C>T p.T125= | Silent (SNP) | VAF 323/707 reads (46%) | catalogued as rs113481990, COSV51528936; called by muse, mutect2, varscan2
- ATP8B4 | c.93T>C p.N31= | Silent (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- CAMKK2 | c.678C>T p.P226= | Silent (SNP) | VAF 314/819 reads (38%) | called by muse, mutect2, varscan2
- CDC42BPB | c.4440C>T p.S1480= | Silent (SNP) | VAF 280/595 reads (47%) | called by muse, mutect2, varscan2
- CST4 | c.6C>T p.A2= | Silent (SNP) | VAF 264/566 reads (47%) | called by muse, mutect2
- EMSY | c.237T>C p.I79= | Silent (SNP) | VAF 286/577 reads (50%) | catalogued as COSV100595726; called by muse, mutect2, varscan2
- PDLIM2 | c.81C>T p.I27= (on ENST00000397760; = p.I277= on NM_021630.6) | Silent (SNP) | VAF 19/419 reads (5%) | called by muse, mutect2
- RFNG | c.384C>T p.S128= | Silent (SNP) | VAF 258/538 reads (48%) | catalogued as rs780399446; called by muse, mutect2, varscan2
- SPRR2F | c.144G>A p.Q48= | Silent (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- H3C2 | c.*50A>G | 3'UTR (SNP) | VAF 83/148 reads (56%) | called by muse, mutect2, varscan2
- MROH8 | c.370+2419T>G | Intron (SNP) | VAF 24/718 reads (3%) | called by muse, mutect2
- NAA60 | c.573-24del | Intron (DEL) | VAF 105/274 reads (38%) | called by mutect2, pindel, varscan2
- RAPGEF3 | c.2323-23G>A | Intron (SNP) | VAF 216/458 reads (47%) | catalogued as rs953652829; called by muse, mutect2, varscan2
- SMC4 | c.1122-44G>T | Intron (SNP) | VAF 90/180 reads (50%) | called by muse, mutect2, varscan2
- TEX12 | c.-36G>A | 5'UTR (SNP) | VAF 126/259 reads (49%) | catalogued as rs772546781; called by muse, mutect2, varscan2
